Surgical pathology report (de-identified scan), TCGA case TCGA-F7-A50I, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Asterand, specimen TCGA-F7-A50I-01A (Primary Tumor).

[page 1 of 3]
Gross Description: Specimen F is designated "total laryngectomy." The specimen consists of a total laryngectomy (9.5 x 8.7 x 7.2 cm), including hyaloid bone (9.2 cm in length x 1.2 cm in diameter), anterior skin with a tracheotomy site (3.1 x 2.0 cm), and anterior strap muscles. The external surface is inked black. The specimen is opened from the posterior midline revealing a tan-pink infiltrative mass (6.2 x 5.1 x 5.8 cm) located in the preepiglottic, glottic and subglottic regions. This mass crosses the midline and involves the true and false vocal cords bilaterally and extends into the tracheostomy site. Sectioning the mass demonstrates extension into the underlying soft tissues and comes within 0.8 cm of the vallecula margin, 0.2 cm from the skin, 0.3 cm from the anterior strap muscles, and 0.2 cm from the anterior surface. This mass involves the thyroid cartilage and cricoid cartilage. This mass appears to extend to the distal tracheal ring margin grossly. The surrounding mucosa is pink tan. No additional lesions are present. Representative sections are submitted as F1-F20. Representative tissue was procured for potential future studies.

Photographs were taken. Specimen F is designated "total laryngectomy." The specimen consists of a total laryngectomy (9.5 x 8.7 x 7.2 cm), including hyaloid bone (9.2 cm in length x 1.2 cm in diameter), anterior skin with a tracheotomy site (3.1 x 2.0 cm), and anterior strap muscles. The external surface is inked black. The specimen is opened from the posterior midline revealing a tan-pink infiltrative mass (6.2 x 5.1 x

ICD-0-3

carcinoma, squamous cell, NOS
8070/3

Site: larynx, NOS
C32.9

w/
10/29/12

[page 2 of 3]
5.8 cm) located in the preepiglottic, glottic and subglottic regions.

This mass crosses the midline and involves the true and false vocal cords bilaterally and extends into the tracheostomy site. Sectioning the mass demonstrates extension into the underlying soft tissues and comes within 0.8 cm of the vallecula margin, 0.2 cm from the skin, 0.3 cm from the anterior strap muscles, and 0.2 cm from the anterior surface. This mass involves the thyroid cartilage and cricoid cartilage. This mass appears to extend to the distal tracheal ring margin grossly. The surrounding mucosa is pink tan. No additional lesions are present. Representative sections are submitted as F1-F20. Representative tissue was procured for potential future studies.

Photographs were taken.

Microscopic Description: N/A

Diagnosis Details: Larynx, total laryngectomy:

- Squamous cell carcinoma, moderately differentiated, invasive, arising in a background of squamous cell carcinoma in situ.
- Tumor involves supraglottic, glottic and subglottic regions involving the true and false vocal cords bilaterally, right epiglottic fold and piriform sinus, right arytenoid, with extension to the tracheostomy site.
- Tumor size: 6.2 x 5.8 x 5.1 cm.
- Invasion of thyroid cartilage and cricoid cartilage.
- Lymphovascular invasion identified.
- Margins: Radial margin at left tracheal margin (slide F2) and anterior margin (slide F20) positive for invasive squamous cell

[page 3 of 3]
carcinoma.

- All other margins negative for tumor.

Comments: N/A

Formatted Path Reports: LARYNX TISSUE CHECKLIST

Specimen type: Total laryngectomy

Tumor site: Larynx

Tumor size: 6.2 x 5.8 x 5.1 cm

Histologic type: Squamous cell carcinoma

Histologic grade: Moderately differentiated

Tumor extent: Major thyroid cartilage erosion

Lymph nodes: Not specified

Margins: Involved

Evidence of neo-adjuvant treatment: Not specified

Comments: Tumor also invades cricoid cartilage

Case is Pathologic		

Source: NCI Genomic Data Commons file 4a45a2b9-c13c-4b35-8fd2-816909e2c4f9 (TCGA-F7-A50I.803D1782-4F1E-4D61-B21D-434D5FB85F97.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).